Somatic mutation profile of tumor specimen C3L-03348-03 (aliquot CPT0167050033) from CPTAC case C3L-03348, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 37.6 years (13,721 days).
Specimen C3L-03348-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48dc041f-7d50-45fc-80a4-914ad2730bd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03348-31 (Blood Derived Normal), aliquot CPT0167070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6380cc01-86e7-4584-8d33-aeaa54dbd212

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 23/296 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARAP1 | c.1459G>A p.V487M (on ENST00000393609 / NM_001040118.2; = p.V242M on NM_015242.4) | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs201636463; called by muse, mutect2
- CDC42EP2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs201902468; called by muse, mutect2
- D2HGDH | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV58320312; called by muse, mutect2
- KLF14 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs1052511554; called by muse, mutect2
- MSLNL | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs531803866; called by muse, mutect2
- MUC16 | c.4075G>A p.A1359T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs375554897; called by muse, mutect2
- NPAS4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1471054323, COSV60648685, COSV60652980; called by muse, mutect2
- PCDHB14 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 30/864 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV53388518; called by muse, mutect2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as rs267600806; called by muse, mutect2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2
- CLCC1 | c.1440A>C p.E480D (on ENST00000356970 / NM_001377464.1; = p.E430D on NM_015127.5) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- PRSS55 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- STRIP2 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.273); called by muse, mutect2
- CIC | c.1590C>T p.S530= | Silent (SNP) | VAF 25/493 reads (5%) | catalogued as rs774171984; called by muse, mutect2
- NLRP12 | c.1587C>T p.D529= | Silent (SNP) | VAF 85/676 reads (13%) | catalogued as rs781712648, COSV60743835, COSV60758270; called by muse, mutect2, varscan2
- PRKCSH | c.1530C>T p.A510= | Silent (SNP) | VAF 27/385 reads (7%) | catalogued as rs573119093; called by muse, mutect2
- TOMM40 | c.375G>A p.G125= | Silent (SNP) | VAF 36/236 reads (15%) | called by muse, varscan2
